Gene-level copy-number profile of tumor specimen ALCH-B3BG-TTP1-A from ALCHEMIST case ALCH-B3BG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.8 years (26,964 days).
Specimen ALCH-B3BG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6aff9171-d475-4365-b9a5-5f264198c5b2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3BG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/086bfb7c-0bd5-4fef-83e9-d58423ce8920

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 5,941; copy number 2: 50,705; copy number 3: 2,105; copy number 4: 81; copy number 5: 55; copy number 6: 5; copy number 7: 2; copy number 9: 2; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:11,102,142–11,102,997, 1 gene: RPL6P4.
- chr15:20,344,736–20,359,166, 1 gene: AC026495.1.
- chr15:64,739,891–64,775,589, 2 genes (within-gene range 0–1): RBPMS2, MIR1272.
- chr15:64,841,883–64,868,002, 1 gene (within-gene range 0–2): PLEKHO2.
- chr16:83,929,796–83,931,223, 1 gene (within-gene range 0–2): AC009119.2.
- chr17:352,638–357,581, 2 genes (within-gene range 0–1): AC129507.2, AC129507.3.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 65 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:46,698,940–48,379,295, 38 genes, copy number 5–6 (within-gene range 4–6): LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP, MSH2, KCNK12, MSH2-OT1, AC079250.1, MSH6, NME2P2, AC006509.1, U6, FBXO11, RPL36AP15, RPS27AP7, AC079807.1, AC092650.1, PPIAP62, VN1R18P, RN7SKP224, FOXN2, RNU4-49P.
- chr8:143,716,340–143,738,234, 4 genes, copy number 5–7: MAPK15, AC105219.1, FAM83H, MIR4664.
- chr8:144,078,002–144,108,124, 7 genes, copy number 5 (within-gene range 2–5): AC109322.1, EXOSC4, MIR6847, GPAA1, CYC1, SHARPIN, MAF1.
- chr9:27,937,617–28,888,955, 7 genes, copy number 5–9: AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873.
- chr22:21,103,016–21,203,755, 7 genes, copy number 5–22: BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A.
- chr22:21,228,760–21,229,138, 1 gene, copy number 5: AP000550.3.
- chr22:21,290,760–21,294,586, 1 gene, copy number 5: BCRP6.

Autosomal genes at a single copy (total copy number 1): 3,085. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
